Surgical pathology report (de-identified scan), TCGA case TCGA-KV-A74V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Hartford, specimen TCGA-KV-A74V-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

#1-EXCISION, FAT (PERINEPHRIC): FAT (NO TUMOR PRESENT).

#2-RESECTION, (PARTIAL), KIDNEY (RIGHT): RENAL PAPILLARY CARCINOMA -

Histologic type:	Renal papillary carcinoma, type 2
Sarcomatoid features:	Not identified
Tumor Necrosis	Focally present
Tumor size:	2.5 cm
Fuhrman nuclear grade:	NA (ISUP nucleolar grade 2)
*Tumor site:	Right kidney
Tumor focality:	Unifocal
Macroscopic extent of tumor:	Confined to kidney
Microscopic extent of tumor:	Confined to kidney
Lymphatic/vascular invasion:	Absent
Margins:	Renal parenchymal margin - negative
-	Perinephric fat/capsular margin-negative (specimens #1, #2)
Non-neoplastic kidney:	No significant findings
Adrenal gland:	Not present.
Lymph nodes:	Not present
pTNM:	pT1a
AJCC STAGE:	Stage I (assumes cN0 cM0)

ICD-O-3
Carcinoma, renal papillary
8260/3
Site R Kidney NOS
C64.9
JW 8/22/13

Electronically Signed Out

COMMENT

88307

Clinical Diagnosis and History:

Right renal mass

Tissue(s) Submitted:

- 1: PERINEPHRIC FAT
- 2: RIGHT RENAL MASS AND SURROUNDING FAT

Gross Description:

[page 2 of 2]
Surgical Pathology Report

Specimen #1 is received in formalin labeled perinephric fat and consists of a 5.0 x 5.0 x 1.5 cm aggregate of tan-yellow, soft to lobulated fibroadipose tissue. The specimen is serially sectioned and no gross lesions are identified. Representative sections are submitted labeled 1A-1B.

Specimen #2 is received fresh for intraoperative consultation labeled right renal mass and surrounding fat and consists of a 9 gram, 3.6 x 3.0 x 3.0 cm partial nephrectomy specimen. The parenchymal margin is inked in blue, the capsule is inked in black. The parenchymal margin appears intact and the capsule margin appears smooth, and intact. The specimen is serially sectioned to identify a 2.5 x 2.2 x 1.6 cm tan-pink, focally hemorrhagic mass measuring 0.2 cm from the nearest parenchymal margin and abutting the capsule. The adjacent renal parenchyma is tan-brown, soft. A representative portion of the normal and mass are submitted for TCGA study. Representative sections are submitted labeled as follows:

2A-2F: tumor to adjacent parenchyma and capsule (2A closest parenchymal margin)
2G: uninvolved parenchyma
2H: surrounding adipose tissue.

Intraoperative Consult Diagnosis

2A/GDX: TUMOR MEASURES ~2MM AWAY FROM THE CLOSEST PARENCHYMAL MARGIN.

I-IPVA Discrepancy		☒

END OF REPORT

Source: NCI Genomic Data Commons file 370c715c-9048-46e3-b8eb-a59c38c0b4fd (TCGA-KV-A74V.6B180151-FFD6-4261-8B60-80BC3C28E210.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).